Somatic mutation profile of tumor specimen TCGA-CZ-5470-01A (aliquot TCGA-CZ-5470-01A-01D-1501-10) from TCGA case TCGA-CZ-5470, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 72.5 years (26,494 days).
Specimen TCGA-CZ-5470-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07e033b6-5684-4908-9fbd-f89192f90649.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5470-11A (Solid Tissue Normal), aliquot TCGA-CZ-5470-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e061561-4522-44bf-a74f-a67d3f74e304

The open-access MAF lists 54 somatic variants for this specimen: 45 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Frame Shift Del 6, Silent 6, Nonsense Mutation 5, Splice Site 2, Splice Region 2, Intron 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.343C>A p.H115N | Missense Mutation (SNP) | VAF 53/140 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as CD141839, CM961423, CM982005, COSV56545369, COSV56546151, COSV56556158, COSV56571206; called by muse, mutect2, varscan2
- ALCAM | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs747080030, COSV60255486; called by muse, mutect2, varscan2
- ARIH1 | c.602T>G p.L201R | Missense Mutation (SNP) | VAF 120/926 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65913116; called by muse, mutect2, varscan2
- ATP2B2 | c.518G>T p.W173L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV59507888; called by muse, mutect2
- CBLN1 | c.368A>G p.N123S | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV54655167; called by muse, mutect2
- CCDC120 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs782744674, COSV64515835; called by muse, mutect2, varscan2
- CDH19 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 40/571 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.305); catalogued as COSV50979788; called by muse, mutect2
- CHL1 | c.110T>A p.I37N | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56607772; called by muse, mutect2, varscan2
- CHMP4B | c.329del p.G110Afs*7 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as COSV99459768; called by mutect2, pindel, varscan2
- CMTR1 | c.2400C>G p.F800L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV64982893; called by muse, varscan2
- CYP2A6 | c.1373A>T p.Q458L | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99992247; called by muse, varscan2
- DAB1 | c.1009G>A p.G337S (on ENST00000371231; = p.G304S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64698692; called by muse, mutect2
- DAPK3 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV56665275; called by muse, mutect2, varscan2
- DRP2 | c.2708C>T p.P903L | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1174296882; called by muse, mutect2
- FEM1C | c.1706A>G p.D569G | Missense Mutation (SNP) | VAF 82/370 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.205); catalogued as COSV57232970; called by muse, varscan2
- GIGYF2 | c.2937_2945del p.Q982_Q984del | In Frame Del (DEL) | VAF 11/65 reads (17%) | catalogued as rs765739152; called by mutect2, pindel
- GZF1 | c.1916T>G p.L639R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV57638887; called by muse, mutect2
- HIVEP1 | c.5159C>A p.S1720* | Nonsense Mutation (SNP) | VAF 36/129 reads (28%) | catalogued as COSV65105367; called by muse, mutect2, varscan2
- ITGB1 | c.2000A>G p.Y667C | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); catalogued as COSV56487207; called by muse, mutect2, varscan2
- JUN | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.339); catalogued as COSV64665019; called by muse, mutect2, varscan2
- KCNT2 | c.2635C>T p.R879* | Nonsense Mutation (SNP) | VAF 75/236 reads (32%) | catalogued as rs759922633, COSV54071953; called by muse, mutect2, varscan2
- KIF14 | c.3136C>G p.R1046G | Missense Mutation (SNP) | VAF 179/706 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV66264306; called by muse, mutect2, varscan2
- KIF1A | c.2746C>T p.Q916* | Nonsense Mutation (SNP) | VAF 22/109 reads (20%) | catalogued as COSV57502853; called by muse, mutect2, varscan2
- LCP2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 63/287 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV50469196; called by muse, mutect2, varscan2
- LRP12 | c.2011G>A p.V671I | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV52635087; called by muse, mutect2, varscan2
- MLLT10 | c.1673C>G p.S558* | Nonsense Mutation (SNP) | VAF 25/888 reads (3%) | catalogued as COSV57005367, COSV57005643; called by muse, mutect2
- MSR1 | c.103+1G>A p.X35_splice | Splice Site (SNP) | VAF 25/125 reads (20%) | catalogued as rs150131889, COSV50506951; called by muse, mutect2, varscan2
- NES | c.2672C>T p.S891L | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63962917, COSV63963417; called by muse, mutect2
- NFKBIZ | c.1420G>T p.D474Y | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58202149; called by muse, mutect2, varscan2
- OR6V1 | c.500G>A p.C167Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289364037, COSV69237021; called by muse, mutect2, varscan2
- PYGL | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV53589006; called by muse, mutect2
- RBM12B | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV66968266, COSV66968411; called by muse, mutect2
- RNF144A | c.583G>C p.D195H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57985599; called by muse, mutect2, varscan2
- SERPINI2 | c.966T>C p.D322= | Splice Region (SNP) | VAF 12/248 reads (5%) | catalogued as COSV52989150; called by muse, mutect2
- SETD2 | c.2917A>T p.R973* | Nonsense Mutation (SNP) | VAF 38/129 reads (29%) | catalogued as COSV57453413; called by muse, mutect2, varscan2
- SLC2A8 | c.1343G>A p.C448Y | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64895193; called by muse, mutect2, varscan2
- TAF1 | c.2299C>T p.P767S (on ENST00000373790 / NM_138923.4; = p.P788S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 241/736 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV52126616; called by muse, varscan2
- TRRAP | c.1353T>C p.V451= | Splice Region (SNP) | VAF 13/92 reads (14%) | catalogued as COSV62855239; called by muse, mutect2, varscan2
- USF1 | c.389del p.G130Vfs*33 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs1374448785; called by mutect2, pindel, varscan2
- BAP1 | c.68-23_69del p.X23_splice | Splice Site (DEL) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- KCNH6 | c.107T>C p.M36T | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.315); called by muse, mutect2
- PBRM1 | c.3589del p.I1197Ffs*21 (on ENST00000296302 / NM_001366071.2; = p.I1172Ffs*21 on NM_018313.5) | Frame Shift Del (DEL) | VAF 157/473 reads (33%) | called by mutect2, pindel, varscan2
- PROS1 | c.1529del p.V510Gfs*3 | Frame Shift Del (DEL) | VAF 47/161 reads (29%) | called by mutect2, pindel, varscan2
- PVR | c.864del p.F289Lfs*10 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- ZNF385A | c.751del p.E251Nfs*26 (on ENST00000338010 / NM_001130967.3; = p.E231Nfs*26 on NM_015481.3) | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by pindel, varscan2
- ANKHD1-EIF4EBP3 | c.4803C>T p.C1601= | Silent (SNP) | VAF 92/393 reads (23%) | catalogued as COSV51859512; called by muse, mutect2, varscan2
- CLCN1 | c.723C>A p.I241= | Silent (SNP) | VAF 20/166 reads (12%) | catalogued as COSV58374824; called by muse, mutect2, varscan2
- FN1 | c.651A>T p.G217= | Silent (SNP) | VAF 11/146 reads (8%) | catalogued as COSV60565125; called by muse, mutect2
- KIAA0232 | c.2304G>A p.Q768= | Silent (SNP) | VAF 16/254 reads (6%) | catalogued as COSV56929757; called by muse, mutect2
- MAGEC1 | c.183G>A p.E61= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV53575685, COSV53582256; called by muse, mutect2, varscan2
- PLEKHO2 | c.663G>A p.R221= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV60263095; called by muse, mutect2, varscan2
- LINC02843 | n.284C>G | RNA (SNP) | VAF 83/333 reads (25%) | called by muse, mutect2
- WNK1 | c.2140-3083A>G | Intron (SNP) | VAF 42/136 reads (31%) | catalogued as rs1448639858, COSV60046359; called by muse, mutect2
- ZNF655 | c.137-510C>A | Intron (SNP) | VAF 82/276 reads (30%) | catalogued as COSV53160324; called by muse, mutect2, varscan2
